Somatic mutation profile of tumor specimen C3N-02030-01 (aliquot CPT0133760080) from CPTAC case C3N-02030, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.7 years (22,893 days).
Specimen C3N-02030-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf962216-65e8-4af1-8d15-dd79a190f692.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02030-71 (Blood Derived Normal), aliquot CPT0133880002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56961f5d-f6fe-4fac-9fc2-f375d8191cbf

The open-access MAF lists 656 somatic variants for this specimen: 441 protein-altering or splice-affecting, 135 silent, 80 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 291, Silent 135, Frame Shift Del 91, Intron 37, Frame Shift Ins 21, 3'UTR 17, Nonsense Mutation 16, 5'UTR 12, Splice Site 8, Splice Region 7, RNA 7, In Frame Del 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 123/319 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 54/97 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- GRM1 | c.26dup p.A11Sfs*78 | Frame Shift Ins (INS) | VAF 104/305 reads (34%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- JAG1 | c.311del p.G104Afs*57 | Frame Shift Del (DEL) | VAF 85/272 reads (31%) | catalogued as rs886041782; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MLH1 | c.1489dup p.R497Pfs*6 | Frame Shift Ins (INS) | VAF 106/351 reads (30%) | catalogued as rs63750855; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.103A>G p.M35V | Missense Mutation (SNP) | VAF 55/172 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs876659443, CM110119, COSV64289131, COSV64291926, COSV64310633; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 219/431 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TECTA | c.5977C>T p.R1993* | Nonsense Mutation (SNP) | VAF 96/258 reads (37%) | catalogued as rs760574657; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs755655007, COSV99367987; called by muse, mutect2, varscan2
- ABCA8 | c.4036G>A p.V1346M | Missense Mutation (SNP) | VAF 77/155 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs767871494, COSV52201017; called by muse, mutect2, varscan2
- ABCB9 | c.1672del p.L558Wfs*24 (on ENST00000280560 / NM_019625.4; = p.L515Wfs*24 on NM_019624.3) | Frame Shift Del (DEL) | VAF 57/170 reads (34%) | catalogued as rs1334723787; called by mutect2, pindel, varscan2
- ABCC1 | c.2656G>A p.V886I | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs756648375; called by muse, mutect2, varscan2
- ACOT7 | c.1090C>T p.R364W (on ENST00000377855 / NM_181864.3; = p.R354W on NM_007274.4) | Missense Mutation (SNP) | VAF 36/352 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781024703, COSV64111974; called by muse, mutect2
- ADAM8 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 84/376 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as rs1027697833; called by muse, mutect2, varscan2
- AEBP1 | c.2383del p.E795Rfs*32 | Frame Shift Del (DEL) | VAF 97/340 reads (29%) | catalogued as COSV56260153; called by mutect2, pindel, varscan2
- AGO2 | c.1806del p.A603Pfs*92 | Frame Shift Del (DEL) | VAF 62/178 reads (35%) | catalogued as rs748399150; called by mutect2, pindel, varscan2
- AKAP8 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs537526016; called by muse, mutect2, varscan2
- ALDH7A1 | c.1061A>T p.Y354F | Missense Mutation (SNP) | VAF 95/269 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as CM121731; called by muse, mutect2, varscan2
- ANKRD18A | c.1826A>G p.Q609R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.403); catalogued as rs1349473073; called by muse, varscan2
- ANKRD60 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.86); catalogued as rs1428760665; called by muse, mutect2
- AOX1 | c.3902C>T p.T1301I | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs758532219; called by muse, mutect2, varscan2
- APC2 | c.1964G>A p.R655H | Missense Mutation (SNP) | VAF 84/204 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as rs1476993748; called by muse, mutect2, varscan2
- APEX2 | c.1030G>T p.V344F | Missense Mutation (SNP) | VAF 75/179 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs1374661061; called by muse, mutect2, varscan2
- APOA5 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 175/492 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM120394; called by muse, mutect2, varscan2
- ASPM | c.6028G>A p.G2010R | Missense Mutation (SNP) | VAF 50/277 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.677); catalogued as rs1327528392; called by muse, mutect2, varscan2
- ATP2B3 | c.2132C>T p.T711M | Missense Mutation (SNP) | VAF 75/277 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99051133; called by muse, mutect2, varscan2
- BCL10 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV65354068; called by muse, mutect2, varscan2
- BLK | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as rs1013048438, COSV52056498; called by muse, mutect2, varscan2
- BMPR1B | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373000965; called by muse, mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 22/42 reads (52%) | catalogued as rs749043197; called by mutect2, varscan2
- CACNB1 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 61/128 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs753711036; called by muse, mutect2, varscan2
- CCDC130 | c.401-8C>T | Splice Region (SNP) | VAF 83/216 reads (38%) | catalogued as rs374818294; called by muse, mutect2, varscan2
- CCDC7 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1055718131, COSV99511956; called by muse, mutect2, varscan2
- CD59 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 122/355 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.044); catalogued as COSV100681242; called by muse, mutect2, varscan2
- CEBPA | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 204/549 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781549846; called by muse, mutect2, varscan2
- COL14A1 | c.1321+1G>A p.X441_splice | Splice Site (SNP) | VAF 30/65 reads (46%) | catalogued as rs775204866, COSV52852671; called by muse, mutect2, varscan2
- COL18A1 | c.4289del p.P1430Lfs*16 (on ENST00000359759 / NM_130444.3; = p.P1195Lfs*16 on NM_030582.4) | Frame Shift Del (DEL) | VAF 204/478 reads (43%) | catalogued as rs748210520; called by mutect2, varscan2
- COL26A1 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 22/251 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV58130844; called by muse, mutect2
- COL27A1 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs781277879, COSV61925278; called by muse, mutect2
- CPAMD8 | c.1994C>T p.A665V (on ENST00000651564; = p.A618V on NM_015692.5) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV52234755; called by muse, mutect2, varscan2
- CPT1C | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs1481092171; called by muse, mutect2, varscan2
- CREBRF | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs753152974, COSV51633080; called by muse, mutect2, varscan2
- CWF19L2 | c.977del p.N326Ifs*19 | Frame Shift Del (DEL) | VAF 27/90 reads (30%) | catalogued as COSV56519025; called by mutect2, pindel, varscan2
- CYP4V2 | c.769_770del p.S257Pfs*14 | Frame Shift Del (DEL) | VAF 90/343 reads (26%) | catalogued as rs767723431; called by pindel, varscan2
- DAPK3 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs756550520, COSV56662684; called by muse, mutect2
- DBH | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 146/375 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs199566547; called by muse, mutect2, varscan2
- DENND2C | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.801); catalogued as rs368033699; called by muse, mutect2, varscan2
- DIP2C | c.2521G>A p.V841M | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs753413734; called by muse, mutect2
- DMBT1 | c.7462C>T p.R2488C (on ENST00000338354 / NM_001377530.1; = p.R1731C on NM_004406.3) | Missense Mutation (SNP) | VAF 125/512 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs1437407547; called by muse, mutect2, varscan2
- DOCK5 | c.966del p.F322Lfs*5 | Frame Shift Del (DEL) | VAF 33/109 reads (30%) | catalogued as rs36119599; called by mutect2, pindel, varscan2
- DOP1A | c.3917del p.K1306Rfs*26 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | catalogued as rs1165924757; called by mutect2, pindel, varscan2
- DPYSL4 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs374822669; called by muse, mutect2, varscan2
- DUSP4 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as rs552819707; called by muse, mutect2, varscan2
- DZIP3 | c.2694-1G>A p.X898_splice | Splice Site (SNP) | VAF 32/88 reads (36%) | catalogued as rs1420268774; called by mutect2, varscan2
- EDA2R | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1405035417; called by muse, mutect2, varscan2
- ELF4 | c.1456C>T p.L486F | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV57452606; called by muse, mutect2, varscan2
- ERLIN2 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 64/501 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374289791; called by muse, mutect2, varscan2
- FAM131B | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 138/389 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs759366087, COSV58367322, COSV58375458; called by muse, mutect2, varscan2
- FANCC | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV56658871; called by muse, mutect2, varscan2
- FASN | c.4655G>A p.R1552H | Missense Mutation (SNP) | VAF 93/224 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs774834763, COSV60760160; called by muse, mutect2, varscan2
- FBXO10 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs536164018, COSV52832293; called by muse, mutect2
- FLG | c.5852G>A p.R1951K | Missense Mutation (SNP) | VAF 202/955 reads (21%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.677); catalogued as COSV64242052; called by muse, mutect2, varscan2
- FOXD3 | c.1178G>A p.G393D | Missense Mutation (SNP) | VAF 83/186 reads (45%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.074); catalogued as rs943720041; called by muse, mutect2, varscan2
- FRA10AC1 | c.694del p.R232Efs*96 | Frame Shift Del (DEL) | VAF 28/126 reads (22%) | catalogued as rs775948504; called by mutect2, varscan2
- FRYL | c.989del p.L330* | Frame Shift Del (DEL) | VAF 42/109 reads (39%) | catalogued as rs1348158626; called by mutect2, varscan2
- FSCN2 | c.1071_1073del p.K357del | In Frame Del (DEL) | VAF 58/192 reads (30%) | catalogued as rs760309853; called by pindel, varscan2
- FSCN3 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 83/219 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs182430717; called by muse, mutect2, varscan2
- FUBP1 | c.1345-5del | Splice Region (DEL) | VAF 48/124 reads (39%) | catalogued as rs545766306; called by mutect2, varscan2
- FZD7 | c.1609A>G p.T537A | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.036); catalogued as rs1342968635; called by muse, mutect2, varscan2
- GBE1 | c.2011del p.S671Lfs*36 | Frame Shift Del (DEL) | VAF 23/100 reads (23%) | catalogued as rs780374709; called by mutect2, pindel, varscan2
- GDF6 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 110/292 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV54625250, COSV54626250; called by muse, mutect2, varscan2
- GPAM | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 122/397 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs760239867, COSV62081256; called by muse, mutect2, varscan2
- GPRIN1 | c.1895C>T p.P632L | Missense Mutation (SNP) | VAF 18/285 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs780573190, COSV56135736; called by muse, mutect2
- GRIN2C | c.1624G>A p.V542I | Missense Mutation (SNP) | VAF 85/228 reads (37%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); catalogued as rs1475521396; called by muse, mutect2, varscan2
- GRM7 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 101/316 reads (32%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.992); catalogued as rs761616232; called by muse, mutect2, varscan2
- HEBP2 | c.593dup p.N198Kfs*2 | Frame Shift Ins (INS) | VAF 33/113 reads (29%) | catalogued as rs769528102; called by mutect2, varscan2
- HNRNPA1 | c.18T>G p.S6= | Splice Region (SNP) | VAF 34/99 reads (34%) | catalogued as rs755898648; called by muse, mutect2, varscan2
- HOXB9 | c.590C>A p.T197K | Missense Mutation (SNP) | VAF 97/239 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60817538; called by muse, mutect2, varscan2
- HPCA | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 122/310 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs749485354, COSV65103324; called by muse, mutect2, varscan2
- HPS1 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 145/503 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753635327, COSV57268666; called by muse, mutect2, varscan2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | catalogued as rs748579647; called by mutect2, pindel, varscan2
- IARS2 | c.69del p.T24Rfs*50 | Frame Shift Del (DEL) | VAF 25/168 reads (15%) | catalogued as COSV56964106; called by mutect2, pindel
- IFI44L | c.204T>A p.N68K | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.91); PolyPhen benign (0.067); catalogued as rs1183417767; called by muse, mutect2, varscan2
- IGF1 | c.579del p.G194Efs*8 | Frame Shift Del (DEL) | VAF 56/185 reads (30%) | catalogued as rs1565968684, COSV61032034; called by mutect2, pindel, varscan2
- IRX5 | c.278T>C p.M93T | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs769740301; called by muse, mutect2
- ITLN1 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370631307, COSV58273846; called by muse, mutect2, varscan2
- KANK4 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 116/308 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as rs373246857, COSV62986738; called by muse, mutect2, varscan2
- KATNIP | c.215A>G p.Y72C | Missense Mutation (SNP) | VAF 84/202 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766133134; called by muse, mutect2, varscan2
- KBTBD7 | c.167_169del p.F56del | In Frame Del (DEL) | VAF 120/319 reads (38%) | catalogued as rs1418828287; called by mutect2, pindel, varscan2
- KCNH3 | c.2123del p.G708Efs*11 | Frame Shift Del (DEL) | VAF 46/187 reads (25%) | catalogued as rs1229306184; called by mutect2, pindel, varscan2
- KLHL26 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.351); catalogued as rs749078539; called by muse, mutect2, varscan2
- KSR1 | c.2042C>T p.T681M (on ENST00000644974 / NM_001367810.1; = p.T566M on NM_014238.2) | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.633); catalogued as rs1363963229, COSV99258826; called by muse, mutect2, varscan2
- LAGE3 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as COSV62074504; called by muse, mutect2, varscan2
- LRRC53 | c.1424T>C p.I475T | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1322380211; called by muse, mutect2, varscan2
- LTB | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs567302751, COSV53000420; called by muse, mutect2, varscan2
- MAN2C1 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 115/267 reads (43%) | catalogued as COSV99145269; called by muse, mutect2, varscan2
- MED13L | c.3686T>A p.L1229H | Missense Mutation (SNP) | VAF 111/280 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99928480; called by muse, mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 34/206 reads (17%) | catalogued as rs745558596; called by mutect2, pindel, varscan2
- MKS1 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 20/422 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as rs780007842, COSV58306097; called by muse, mutect2
- MPDU1 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 153/400 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs764397720; called by muse, mutect2, varscan2
- MTERF3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs750850029; called by muse, mutect2, varscan2
- MUC17 | c.12128G>A p.R4043H | Missense Mutation (SNP) | VAF 23/257 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.046); catalogued as rs147525614; called by muse, mutect2
- MUC5B | c.11872G>A p.G3958S | Missense Mutation (SNP) | VAF 52/670 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs375432828; called by muse, mutect2
- MYLK | c.4813G>T p.D1605Y | Missense Mutation (SNP) | VAF 146/408 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60610051; called by muse, mutect2, varscan2
- MYO3A | c.3341C>T p.T1114I | Missense Mutation (SNP) | VAF 51/226 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV56352031; called by muse, mutect2, varscan2
- MYO3A | c.3574dup p.M1192Nfs*3 | Frame Shift Ins (INS) | VAF 51/248 reads (21%) | catalogued as rs757810767; called by mutect2, varscan2
- NECTIN4 | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 26/821 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1478255615, COSV63513046; called by muse, mutect2
- NFAM1 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 21/274 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61194814; called by muse, mutect2
- NFX1 | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 28/94 reads (30%) | catalogued as rs1451971621; called by muse, mutect2, varscan2
- NIPBL | c.2171C>A p.T724N | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.107); catalogued as COSV56959792; called by muse, mutect2, varscan2
- NKX6-2 | c.358G>A p.G120S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs1447090832; called by muse, mutect2, varscan2
- NR1D1 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52843337; called by muse, mutect2, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 40/109 reads (37%) | catalogued as rs774343392; called by mutect2, varscan2
- NRBP2 | c.1361T>C p.L454P | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs1554651582; called by muse, mutect2, varscan2
- NRROS | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751058757, COSV60744792; called by muse, mutect2, varscan2
- NUDT22 | c.225del p.P76Hfs*52 | Frame Shift Del (DEL) | VAF 86/251 reads (34%) | catalogued as rs755949538; called by mutect2, pindel, varscan2
- ODF3L2 | c.49dup p.L17Pfs*62 | Frame Shift Ins (INS) | VAF 24/86 reads (28%) | catalogued as rs748636054; called by mutect2, pindel, varscan2
- OR52A5 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs1221037254, COSV56615866; called by muse, mutect2, varscan2
- OR5B2 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.393); catalogued as rs199556711; called by muse, mutect2, varscan2
- PAQR9 | c.201del p.C68Afs*7 | Frame Shift Del (DEL) | VAF 30/322 reads (9%) | catalogued as COSV61418111; called by mutect2, pindel
- PAX5 | c.76dup p.V26Gfs*49 | Frame Shift Ins (INS) | VAF 46/118 reads (39%) | catalogued as rs767894241; called by mutect2, varscan2
- PAXIP1 | c.300del p.F100Lfs*31 | Frame Shift Del (DEL) | VAF 32/76 reads (42%) | catalogued as rs753190856; called by mutect2, varscan2
- PBRM1 | c.1730A>G p.N577S | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs115997236; called by muse, mutect2, varscan2
- PCDHA5 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 136/372 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.232); catalogued as COSV65352687, COSV65353320, COSV65354029; called by muse, varscan2
- PCDHB16 | c.1921G>T p.V641L | Missense Mutation (SNP) | VAF 159/460 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53360912; called by muse, mutect2, varscan2
- PCDHGB1 | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as rs780182840, COSV53893504, COSV54007624; called by muse, mutect2, varscan2
- PCNX3 | c.3379G>A p.G1127S | Missense Mutation (SNP) | VAF 25/317 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs747284721; called by muse, mutect2
- PDE2A | c.2266C>T p.R756C | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs138870390, COSV57811844; called by muse, mutect2, varscan2
- PDHA1 | c.464T>C p.M155T | Missense Mutation (SNP) | VAF 33/398 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as CM164678; called by muse, mutect2
- PGAM5 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768706336; called by muse, mutect2, varscan2
- PHACTR4 | c.160del p.S54Vfs*12 (on ENST00000373839 / NM_001350159.2; = p.S64Vfs*12 on NM_023923.4) | Frame Shift Del (DEL) | VAF 48/136 reads (35%) | catalogued as rs761437290, COSV65783432; called by mutect2, varscan2
- PHACTR4 | c.2032G>T p.E678* (on ENST00000373839 / NM_001350159.2; = p.E688* on NM_023923.4) | Nonsense Mutation (SNP) | VAF 30/90 reads (33%) | catalogued as COSV65783415, COSV65785417; called by muse, mutect2, varscan2
- PIK3C2B | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs373236355; called by muse, mutect2, varscan2
- PLD6 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs772007129, COSV58634239; called by muse, mutect2, varscan2
- PLEKHM1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 88/331 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1251964349, COSV69598825; called by muse, mutect2, varscan2
- PLOD3 | c.1728G>A p.M576I | Missense Mutation (SNP) | VAF 36/550 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.277); catalogued as COSV56182376; called by muse, mutect2
- PLXNB3 | c.5080A>G p.T1694A | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1249993822; called by muse, mutect2, varscan2
- PMFBP1 | c.1937G>T p.R646L (on ENST00000537465; = p.R641L on NM_031293.3) | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.363); catalogued as COSV52822054, COSV52825354; called by muse, mutect2, varscan2
- PNPLA7 | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs149697052; called by muse, mutect2, varscan2
- PODXL | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 155/422 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs758337217, COSV59872367; called by muse, mutect2, varscan2
- POLD1 | c.2789C>T p.A930V | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs1060501855; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPRC1 | c.2819del p.P940Hfs*6 | Frame Shift Del (DEL) | VAF 34/145 reads (23%) | catalogued as rs768056539; called by mutect2, varscan2
- PROC | c.1212del p.M406Wfs*15 | Frame Shift Del (DEL) | VAF 48/152 reads (32%) | catalogued as CM951029; called by mutect2, pindel, varscan2
- RAB11FIP5 | c.891del p.K298Sfs*109 | Frame Shift Del (DEL) | VAF 32/87 reads (37%) | catalogued as COSV99241854; called by mutect2, pindel, varscan2
- RANGAP1 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 67/178 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs771897708; called by muse, mutect2, varscan2
- RB1 | c.1959del p.V654Cfs*4 | Frame Shift Del (DEL) | VAF 31/97 reads (32%) | catalogued as CM1110478, COSV57298520; called by mutect2, pindel, varscan2
- RBM20 | c.3210del p.T1071Pfs*33 | Frame Shift Del (DEL) | VAF 86/417 reads (21%) | catalogued as COSV65705579; called by mutect2, pindel, varscan2
- REV3L | c.4055C>T p.T1352M | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); catalogued as rs758477587, COSV62617192; called by muse, mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 16/33 reads (48%) | catalogued as rs751982308; called by mutect2, varscan2
- RILP | c.1150T>C p.C384R | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.452); catalogued as COSV53961695; called by muse, mutect2, varscan2
- RNF11 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1313459994, COSV99657934; called by muse, mutect2, varscan2
- ROBO3 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 51/354 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM090354; called by muse, mutect2, varscan2
- RP1L1 | c.7144G>A p.A2382T | Missense Mutation (SNP) | VAF 108/304 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs776156711, COSV66762092; called by muse, mutect2, varscan2
- RPL7L1 | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100491742; called by muse, mutect2, varscan2
- RTKN | c.193C>T p.R65* (on ENST00000272430 / NM_001015055.2; = p.R52* on NM_033046.2) | Nonsense Mutation (SNP) | VAF 40/312 reads (13%) | catalogued as rs532819376; called by muse, mutect2, varscan2
- RXFP1 | c.1823A>G p.Q608R | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs776423555; called by muse, mutect2, varscan2
- SCARA3 | c.1513G>A p.G505R | Missense Mutation (SNP) | VAF 105/280 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760726180; called by muse, mutect2, varscan2
- SDAD1 | c.824del p.K275Rfs*15 | Frame Shift Del (DEL) | VAF 28/89 reads (31%) | catalogued as rs763181092; called by mutect2, pindel, varscan2
- SETD1B | c.4409C>T p.T1470M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.584); catalogued as rs1490141875; called by muse, mutect2, varscan2
- SEZ6L2 | c.1691G>A p.R564H (on ENST00000308713 / NM_001114099.3; = p.R494H on NM_012410.4) | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1311011521, COSV58096855; called by muse, mutect2, varscan2
- SH2D5 | c.722G>A p.R241H (on ENST00000444387 / NM_001103161.2; = p.R157H on NM_001103160.2) | Missense Mutation (SNP) | VAF 115/320 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs766370454; called by muse, mutect2, varscan2
- SH3PXD2A | c.1645C>T p.R549W (on ENST00000369774 / NM_001365079.1; = p.R521W on NM_014631.2) | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as rs751523064; called by muse, mutect2, varscan2
- SIGLEC12 | c.622C>A p.P208T (on ENST00000291707 / NM_053003.4; = p.P90T on NM_033329.2) | Missense Mutation (SNP) | VAF 87/248 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV52463588; called by muse, mutect2, varscan2
- SIPA1 | c.748_750del p.K250del | In Frame Del (DEL) | VAF 42/92 reads (46%) | catalogued as rs1333397145; called by mutect2, pindel, varscan2
- SIX4 | c.371del p.G124Afs*26 | Frame Shift Del (DEL) | VAF 37/150 reads (25%) | catalogued as COSV99381980; called by pindel, varscan2
- SLC25A30 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141801271; called by muse, mutect2, varscan2
- SMAD9 | c.787C>T p.R263* (on ENST00000379826 / NM_001127217.3; = p.R226* on NM_005905.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 70/218 reads (32%) | catalogued as rs1205054074, COSV63205853; called by muse, mutect2, varscan2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 19/70 reads (27%) | catalogued as rs763364024; called by mutect2, varscan2
- SMARCC2 | c.3268C>T p.P1090S | Missense Mutation (SNP) | VAF 96/298 reads (32%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.901); catalogued as rs934469841; called by muse, varscan2
- SMG6 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.543); catalogued as rs777483170, COSV53966327; called by muse, mutect2, varscan2
- SPEF2 | c.877dup p.I293Nfs*6 | Frame Shift Ins (INS) | VAF 35/116 reads (30%) | catalogued as rs1390109415; called by mutect2, varscan2
- SPTBN5 | c.5171G>A p.R1724Q | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs199701887; called by muse, mutect2, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/86 reads (26%) | catalogued as rs770033147; called by mutect2, varscan2
- SYNE1 | c.10196G>A p.R3399Q (on ENST00000367255 / NM_182961.4; = p.R3406Q on NM_033071.3) | Missense Mutation (SNP) | VAF 86/241 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.32); catalogued as rs368647352; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TACC3 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as rs766595415; called by muse, mutect2, varscan2
- TAF1 | c.1877del p.K626Rfs*4 (on ENST00000373790 / NM_138923.4; = p.K647Rfs*4 on NM_004606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 38/119 reads (32%) | catalogued as rs745516519; called by mutect2, varscan2
- TANC1 | c.4951T>C p.C1651R | Missense Mutation (SNP) | VAF 35/290 reads (12%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.1); catalogued as COSV55082619; called by muse, mutect2, varscan2
- TBC1D1 | c.928del p.I310* | Frame Shift Del (DEL) | VAF 48/142 reads (34%) | catalogued as rs760298745; called by mutect2, pindel, varscan2
- TCF25 | c.393del p.K131Nfs*17 | Frame Shift Del (DEL) | VAF 40/108 reads (37%) | catalogued as rs748021112; called by mutect2, varscan2
- TDRKH | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 43/309 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767475622, COSV58617972; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 44/108 reads (41%) | catalogued as rs763321097; called by mutect2, varscan2
- TERF1 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1563459421; called by muse, mutect2, varscan2
- TFCP2L1 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 91/257 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55292626; called by muse, mutect2, varscan2
- TFEB | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs1289665036, COSV57826547; called by muse, mutect2, varscan2
- TMEM125 | c.47del p.P16Rfs*53 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs1254012370; called by mutect2, pindel, varscan2
- TMEM63A | c.783G>C p.Q261H | Missense Mutation (SNP) | VAF 74/455 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs946138520; called by muse, mutect2, varscan2
- TOP3B | c.2470C>T p.R824C | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs1270601428; called by mutect2, varscan2
- TRAV3 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 76/208 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs745851436; called by muse, mutect2, varscan2
- TRIM2 | c.1087G>A p.A363T (on ENST00000437508; = p.A390T on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as rs754123914; called by muse, mutect2, varscan2
- TRIM31 | c.260A>G p.Q87R | Missense Mutation (SNP) | VAF 82/169 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs928628355; called by muse, mutect2, varscan2
- TRIM9 | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 133/356 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV100030317; called by muse, mutect2, varscan2
- TRIO | c.7050del p.V2351Cfs*62 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | catalogued as rs746654944; called by mutect2, pindel, varscan2
- TRPM5 | c.1297C>T p.Q433* | Nonsense Mutation (SNP) | VAF 145/335 reads (43%) | catalogued as rs1467014210; called by muse, mutect2, varscan2
- TUBG2 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as COSV52218597; called by muse, mutect2, varscan2
- ULK1 | c.1799G>A p.R600Q | Missense Mutation (SNP) | VAF 133/376 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as rs745749590; called by muse, mutect2, varscan2
- USP2 | c.825G>A p.T275= | Splice Region (SNP) | VAF 71/205 reads (35%) | catalogued as rs199771100; called by muse, mutect2, varscan2
- VPS33A | c.246del p.F82Lfs*6 | Frame Shift Del (DEL) | VAF 21/60 reads (35%) | catalogued as rs756221452; called by mutect2, varscan2
- VPS37D | c.712del p.L238Cfs*2 | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | catalogued as rs1554609756; called by mutect2, pindel, varscan2
- XIRP1 | c.1228G>A p.G410S | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs775595813, COSV100453679; called by muse, mutect2, varscan2
- ZBED1 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 107/270 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1308585565, COSV58134616; called by muse, mutect2, varscan2
- ZBED8 | c.894_897del p.N299Sfs*21 | Frame Shift Del (DEL) | VAF 61/173 reads (35%) | catalogued as rs1184980267; called by mutect2, pindel, varscan2
- ZBTB40 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 154/407 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs912482215; called by muse, mutect2, varscan2
- ZNF341 | c.2242dup p.Q748Pfs*22 (on ENST00000375200 / NM_001282935.1; = p.Q741Pfs*22 on NM_032819.4) | Frame Shift Ins (INS) | VAF 18/104 reads (17%) | catalogued as rs747874764; called by mutect2, varscan2
- ZNF467 | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100118113; called by muse, mutect2, varscan2
- ZNF48 | c.745dup p.R249Pfs*31 | Frame Shift Ins (INS) | VAF 48/118 reads (41%) | catalogued as rs780189754; called by mutect2, varscan2
- ZNF496 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.184); catalogued as rs758982919, COSV54175637; called by muse, mutect2, varscan2
- AADAT | c.566del p.N189Tfs*20 | Frame Shift Del (DEL) | VAF 57/179 reads (32%) | called by mutect2, pindel, varscan2
- ABCA13 | c.4595T>C p.M1532T | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ABI1 | c.286-1G>A p.X96_splice | Splice Site (SNP) | VAF 28/96 reads (29%) | called by mutect2, varscan2
- ACADSB | c.161T>C p.L54P | Missense Mutation (SNP) | VAF 67/296 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACAP3 | c.1196G>A p.G399D | Missense Mutation (SNP) | VAF 218/544 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACTR8 | c.1017T>A p.D339E | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ADAMTSL4 | c.1783del p.Y595Ifs*29 | Frame Shift Del (DEL) | VAF 91/577 reads (16%) | called by mutect2, pindel, varscan2
- ADGRE5 | c.2203G>A p.A735T (on ENST00000242786 / NM_078481.4; = p.A642T on NM_001784.5) | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- AHI1 | c.2791A>G p.K931E | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, varscan2
- AHNAK2 | c.12265G>A p.A4089T | Missense Mutation (SNP) | VAF 259/641 reads (40%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- AHRR | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- AKAP4 | c.890G>A p.G297D | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- AKAP9 | c.6111dup p.L2038Tfs*8 (on ENST00000359028; = p.L2006Tfs*8 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 27/93 reads (29%) | called by mutect2, pindel, varscan2
- ANKRD31 | c.3134del p.L1045* | Frame Shift Del (DEL) | VAF 29/123 reads (24%) | called by mutect2, pindel, varscan2
- ANKRD31 | c.654_655del p.E218Dfs*23 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel, varscan2
- APOBR | c.2381A>G p.H794R (on ENST00000431282; = p.H803R on NM_018690.4) | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARAP1 | c.2365G>A p.A789T (on ENST00000393609 / NM_001040118.2; = p.A544T on NM_015242.4) | Missense Mutation (SNP) | VAF 85/243 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARHGAP18 | c.1877del p.L626Cfs*19 | Frame Shift Del (DEL) | VAF 47/137 reads (34%) | called by mutect2, pindel, varscan2
- ARHGAP4 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 111/338 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ARX | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ATP1A2 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 105/505 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ATP2B4 | c.49A>C p.S17R | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- BSN | c.9295A>G p.S3099G | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- C16orf89 | c.1120A>G p.T374A | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C3orf20 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 65/206 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- C4orf54 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CAMSAP2 | c.2786T>A p.V929E (on ENST00000236925 / NM_001297707.2; = p.V918E on NM_203459.3) | Missense Mutation (SNP) | VAF 49/283 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- CATSPER1 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- CCNDBP1 | c.710A>C p.D237A | Missense Mutation (SNP) | VAF 74/196 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- CCNT2 | c.281A>T p.E94V | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDYL2 | c.140A>T p.H47L | Missense Mutation (SNP) | VAF 85/234 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- CEACAM1 | c.605_609del p.L202Qfs*6 | Frame Shift Del (DEL) | VAF 136/409 reads (33%) | called by mutect2, pindel, varscan2
- CEACAM19 | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEL | c.1295dup p.S433Efs*29 (on ENST00000673714; = p.S430Efs*29 on NM_001807.6) | Frame Shift Ins (INS) | VAF 9/48 reads (19%) | called by mutect2, varscan2
- CEP135 | c.3247C>T p.R1083* | Nonsense Mutation (SNP) | VAF 43/135 reads (32%) | called by muse, mutect2, varscan2
- CHIT1 | c.536T>C p.L179P | Missense Mutation (SNP) | VAF 189/929 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CKAP2 | c.234+1G>A p.X78_splice (on ENST00000378037 / NM_001098525.2; = p.X77_splice on NM_018204.5) | Splice Site (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- CMIP | c.805C>T p.R269* (on ENST00000537098 / NM_198390.2; = p.R175* on NM_030629.3) | Nonsense Mutation (SNP) | VAF 42/150 reads (28%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.927+2T>C p.X309_splice | Splice Site (SNP) | VAF 27/199 reads (14%) | called by muse, mutect2, varscan2
- COCH | c.1267T>C p.C423R (on ENST00000216361 / NM_001347720.1; = p.C358R on NM_004086.3) | Missense Mutation (SNP) | VAF 124/315 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL11A2 | c.1292dup p.G432Wfs*31 (on ENST00000341947 / NM_080680.3; = p.G325Wfs*31 on NM_080679.2) | Frame Shift Ins (INS) | VAF 50/176 reads (28%) | called by mutect2, pindel, varscan2
- COL2A1 | c.2399A>G p.N800S | Missense Mutation (SNP) | VAF 94/286 reads (33%) | SIFT tolerated (0.84); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- CPN1 | c.577-8C>T | Splice Region (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- CRHR2 | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 79/172 reads (46%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- CSTF2T | c.1427A>G p.Q476R | Missense Mutation (SNP) | VAF 66/236 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- CWF19L2 | c.1398del p.E467Nfs*22 | Frame Shift Del (DEL) | VAF 34/101 reads (34%) | called by mutect2, pindel, varscan2
- DAGLA | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- DELE1 | c.878C>A p.T293N | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHX40 | c.1463A>G p.E488G | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2
- DHX40 | c.2066A>G p.Y689C | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DHX8 | c.2098T>A p.L700M | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DISP3 | c.1008del p.S337Afs*4 | Frame Shift Del (DEL) | VAF 39/163 reads (24%) | called by mutect2, pindel, varscan2
- DLEU7 | c.212del p.G71Afs*20 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | called by mutect2, pindel, varscan2
- DLGAP2 | c.2324C>T p.A775V | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DMTF1 | c.1352C>T p.T451I | Missense Mutation (SNP) | VAF 102/295 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DNAH1 | c.11242C>T p.H3748Y | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- DOCK2 | c.144C>A p.Y48* | Nonsense Mutation (SNP) | VAF 38/131 reads (29%) | called by muse, mutect2, varscan2
- EFCAB2 | c.737G>T p.G246V (on ENST00000366522; = p.G110V on NM_032328.3) | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EHF | c.712A>G p.R238G | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ELF1 | c.906G>T p.E302D | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- EP400 | c.4593G>T p.Q1531H | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- EPS8L1 | c.874C>T p.R292C (on ENST00000201647 / NM_133180.3; = p.R165C on NM_017729.3) | Missense Mutation (SNP) | VAF 76/162 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- EPX | c.2069G>A p.R690K | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT2 | c.6702G>C p.E2234D | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBN2 | c.7240G>T p.G2414C | Missense Mutation (SNP) | VAF 181/458 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- FBXW7 | c.664_667delinsAG p.R223Pfs*32 (on ENST00000281708 / NM_001349798.2; = p.R143Pfs*32 on NM_018315.5) | Frame Shift Del (DEL) | VAF 44/181 reads (24%) | called by pindel, varscan2*
- FMNL1 | c.240dup p.A81Rfs*23 | Frame Shift Ins (INS) | VAF 80/283 reads (28%) | called by mutect2, pindel, varscan2
- FOXE1 | c.1073A>G p.H358R | Missense Mutation (SNP) | VAF 19/625 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.056); called by muse, mutect2
- FOXO3 | c.212del p.G71Dfs*49 | Frame Shift Del (DEL) | VAF 57/176 reads (32%) | called by mutect2, pindel, varscan2
- FOXR2 | c.725A>G p.Y242C | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- FRA10AC1 | c.899A>T p.K300I | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GABRB2 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 101/272 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALR1 | c.57del p.A20Pfs*23 | Frame Shift Del (DEL) | VAF 60/167 reads (36%) | called by mutect2, pindel, varscan2
- GNA15 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GNL1 | c.791C>A p.P264Q | Missense Mutation (SNP) | VAF 85/210 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GOLM2 | c.647del p.N216Ifs*5 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel, varscan2
- GPAM | c.1961G>A p.G654D | Missense Mutation (SNP) | VAF 67/338 reads (20%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR75 | c.719del p.P240Lfs*2 | Frame Shift Del (DEL) | VAF 67/203 reads (33%) | called by mutect2, pindel, varscan2
- GPR82 | c.817dup p.Y273Lfs*8 | Frame Shift Ins (INS) | VAF 26/90 reads (29%) | called by mutect2, pindel, varscan2
- GSTA3 | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- GSTM3 | c.576del p.F192Lfs*63 | Frame Shift Del (DEL) | VAF 78/252 reads (31%) | called by mutect2, pindel, varscan2
- HADHA | c.2285A>G p.Y762C | Missense Mutation (SNP) | VAF 162/418 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- HIVEP2 | c.1091_1092del p.T364Sfs*18 | Frame Shift Del (DEL) | VAF 56/164 reads (34%) | called by pindel, varscan2
- HSPB1 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 177/458 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- ICAM5 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- IGDCC4 | c.1296del p.T433Rfs*8 | Frame Shift Del (DEL) | VAF 61/205 reads (30%) | called by mutect2, pindel, varscan2
- IGFBP5 | c.490A>G p.K164E | Missense Mutation (SNP) | VAF 94/257 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- IGKV1D-37 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by mutect2, varscan2
- IGSF1 | c.2268del p.K756Nfs*17 | Frame Shift Del (DEL) | VAF 60/168 reads (36%) | called by mutect2, pindel, varscan2
- ING1 | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 87/238 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- INPPL1 | c.2974del p.V992Sfs*139 | Frame Shift Del (DEL) | VAF 68/180 reads (38%) | called by mutect2, pindel, varscan2
- IQCB1 | c.1330T>C p.W444R | Missense Mutation (SNP) | VAF 40/261 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IRX3 | c.706del p.E236Rfs*24 | Frame Shift Del (DEL) | VAF 49/144 reads (34%) | called by mutect2, varscan2
- ITGA1 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- ITPR1 | c.3725del p.L1242Cfs*19 (on ENST00000354582; = p.L1227Cfs*19 on NM_002222.7) | Frame Shift Del (DEL) | VAF 30/107 reads (28%) | called by mutect2, pindel, varscan2
- KANK3 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 124/329 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- KAT6B | c.6188_6191del p.K2063Sfs*8 | Frame Shift Del (DEL) | VAF 142/615 reads (23%) | called by mutect2, pindel, varscan2
- KCNA2 | c.1386G>T p.Q462H | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- KCTD13 | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 69/221 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KIAA0319 | c.2353del p.V785Cfs*36 | Frame Shift Del (DEL) | VAF 77/231 reads (33%) | called by mutect2, pindel, varscan2
- KIAA1614 | c.2360A>C p.E787A | Missense Mutation (SNP) | VAF 51/236 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- KIF5B | c.1985A>G p.E662G | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KISS1 | c.169A>C p.K57Q | Missense Mutation (SNP) | VAF 176/923 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KLHDC8A | c.298T>C p.Y100H | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KMT2B | c.4498-1G>C p.X1500_splice | Splice Site (SNP) | VAF 44/117 reads (38%) | called by muse, mutect2, varscan2
- LAMA1 | c.9121A>G p.R3041G | Missense Mutation (SNP) | VAF 105/277 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LAMB3 | c.1970C>A p.S657Y | Missense Mutation (SNP) | VAF 129/733 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- LARP1 | c.911del p.P304Qfs*22 (on ENST00000518297 / NM_033551.3; = p.P227Qfs*22 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 92/269 reads (34%) | called by mutect2, pindel, varscan2
- LHX3 | c.598G>A p.V200M (on ENST00000371748 / NM_178138.6; = p.V205M on NM_014564.5) | Missense Mutation (SNP) | VAF 71/190 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- LINGO4 | c.1578del p.L527Wfs*21 | Frame Shift Del (DEL) | VAF 62/306 reads (20%) | called by mutect2, pindel, varscan2
- LMX1A | c.703A>G p.S235G | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- LMX1A | c.104G>A p.C35Y | Missense Mutation (SNP) | VAF 70/297 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP1 | c.9625C>T p.R3209C | Missense Mutation (SNP) | VAF 114/312 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC31 | c.211A>G p.S71G | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC41 | c.572T>C p.L191P | Missense Mutation (SNP) | VAF 75/178 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC7 | c.3192del p.V1065Sfs*16 (on ENST00000651989 / NM_001370785.2; = p.V1032Sfs*16 on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 75/225 reads (33%) | called by mutect2, pindel, varscan2
- MAGI3 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MANEAL | c.868dup p.H290Pfs*31 (on ENST00000373045 / NM_001113482.1; = p.H68Pfs*31 on NM_152496.2) | Frame Shift Ins (INS) | VAF 109/316 reads (34%) | called by mutect2, pindel, varscan2
- MARK3 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- MARS1 | c.201-5G>T | Splice Region (SNP) | VAF 6/134 reads (4%) | called by muse, mutect2
- MED12 | c.3836C>T p.A1279V | Missense Mutation (SNP) | VAF 129/315 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MEN1 | c.881T>A p.L294Q | Missense Mutation (SNP) | VAF 190/465 reads (41%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MIPEP | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MLH1 | c.725T>C p.M242T | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2
- MRGPRF | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- MRPL27 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 102/273 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO15A | c.2084G>A p.G695D | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NDRG1 | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 88/211 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NKAPD1 | c.479del p.K160Sfs*20 (on ENST00000280352 / NM_001082970.2; = p.K161Sfs*20 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 45/146 reads (31%) | called by mutect2, varscan2
- NLRP6 | c.2254del p.L752* | Frame Shift Del (DEL) | VAF 75/272 reads (28%) | called by mutect2, pindel, varscan2
- NRAP | c.1633-2A>C p.X545_splice (on ENST00000359988 / NM_001322945.2; = p.X510_splice on NM_006175.4) | Splice Site (SNP) | VAF 50/179 reads (28%) | called by muse, mutect2, varscan2
- NUMB | c.944del p.N315Mfs*6 (on ENST00000355058; = p.N304Mfs*6 on NM_003744.5) | Frame Shift Del (DEL) | VAF 9/87 reads (10%) | called by mutect2, pindel, varscan2
- OBSCN | c.6980A>G p.Q2327R | Missense Mutation (SNP) | VAF 130/685 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- OCIAD2 | c.339del p.F113Lfs*27 | Frame Shift Del (DEL) | VAF 42/122 reads (34%) | called by mutect2, pindel, varscan2
- OCLN | c.1048G>A p.V350M | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.108); called by mutect2, varscan2
- OR4D11 | c.786C>A p.F262L | Missense Mutation (SNP) | VAF 80/246 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, varscan2
- ORC1 | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 90/244 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- OSGEP | c.855del p.F285Lfs*14 | Frame Shift Del (DEL) | VAF 47/161 reads (29%) | called by mutect2, pindel, varscan2
- OTOR | c.186del p.Q64Sfs*10 | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | called by mutect2, pindel, varscan2
- PDE3A | c.410T>A p.F137Y | Missense Mutation (SNP) | VAF 10/294 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2
- PES1 | c.845G>A p.S282N | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- PIK3R1 | c.1719_1722del p.K575Rfs*6 (on ENST00000521381 / NM_181523.3; = p.K305Rfs*6 on NM_181504.4) | Frame Shift Del (DEL) | VAF 32/99 reads (32%) | called by mutect2, pindel, varscan2
- PKP2 | c.752G>C p.S251T | Missense Mutation (SNP) | VAF 140/388 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- PLEKHH3 | c.1589dup p.P531Tfs*114 | Frame Shift Ins (INS) | VAF 22/60 reads (37%) | called by mutect2, pindel, varscan2
- PLEKHM3 | c.1868C>T p.A623V | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PLEKHM3 | c.1397A>T p.Q466L | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLPPR3 | c.1261C>A p.L421M (on ENST00000520876 / NM_001270366.2; = p.L449M on NM_024888.2) | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.213); called by muse, mutect2
- POLK | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- POSTN | c.2126C>A p.P709H | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- POU3F3 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 154/344 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- PPP2R5E | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); called by muse, varscan2
- PPP4R3A | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP5C | c.46del p.R16Gfs*10 | Frame Shift Del (DEL) | VAF 51/170 reads (30%) | called by mutect2, pindel, varscan2
- PRSS56 | c.380A>G p.Q127R | Missense Mutation (SNP) | VAF 79/213 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PSMB10 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT tolerated (0.86); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTPN1 | c.1130del p.G377Efs*27 | Frame Shift Del (DEL) | VAF 22/84 reads (26%) | called by mutect2, pindel, varscan2
- PTPN13 | c.1505G>A p.S502N | Missense Mutation (SNP) | VAF 129/330 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTPRQ | c.1045G>T p.G349* (on ENST00000616559; = p.G307* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 34/99 reads (34%) | called by muse, mutect2, varscan2
- R3HCC1L | c.1430del p.K477Rfs*18 | Frame Shift Del (DEL) | VAF 37/144 reads (26%) | called by mutect2, pindel, varscan2
- RAB30 | c.452C>T p.T151I | Missense Mutation (SNP) | VAF 35/263 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RASSF8 | c.1073C>T p.T358I | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- RB1 | c.1212del p.F404Lfs*6 | Frame Shift Del (DEL) | VAF 24/97 reads (25%) | called by mutect2, pindel, varscan2
- RET | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 159/609 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- RET | c.626-1G>T p.X209_splice | Splice Site (SNP) | VAF 114/446 reads (26%) | called by muse, mutect2, varscan2
- REV3L | c.1362T>A p.N454K | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- RFPL4AL1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- RFX1 | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 78/210 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF186 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 141/341 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- RNF31 | c.1371del p.K458Sfs*34 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | called by mutect2, pindel
- RSPO3 | c.458G>A p.W153* | Nonsense Mutation (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- SCAF4 | c.2156del p.P719Lfs*29 | Frame Shift Del (DEL) | VAF 51/153 reads (33%) | called by mutect2, pindel, varscan2
- SCG2 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.602); called by muse, mutect2
- SCG3 | c.215_217del p.V72del | In Frame Del (DEL) | VAF 32/86 reads (37%) | called by pindel, varscan2
- SCN4A | c.4933G>A p.D1645N | Missense Mutation (SNP) | VAF 92/220 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- SCO2 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 219/574 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERPINA7 | c.107dup p.N36Kfs*11 | Frame Shift Ins (INS) | VAF 35/126 reads (28%) | called by mutect2, pindel, varscan2
- SHISA6 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 259/683 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- SHLD2 | c.1285del p.T429Hfs*3 | Frame Shift Del (DEL) | VAF 22/100 reads (22%) | called by mutect2, varscan2
- SHROOM4 | c.3941del p.K1314Rfs*23 | Frame Shift Del (DEL) | VAF 56/163 reads (34%) | called by mutect2, varscan2
- SLC25A14 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SLC25A23 | c.1111T>A p.S371T | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC30A7 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SLC39A10 | c.1040A>T p.Y347F | Missense Mutation (SNP) | VAF 62/159 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC4A8 | c.2108dup p.T704Hfs*13 | Frame Shift Ins (INS) | VAF 48/207 reads (23%) | called by mutect2, pindel, varscan2
- SLC8A2 | c.107G>T p.S36I | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- SLITRK1 | c.347A>T p.N116I | Missense Mutation (SNP) | VAF 147/360 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLMAP | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLX4 | c.1972C>T p.P658S | Missense Mutation (SNP) | VAF 198/552 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.219); called by muse, mutect2
- SNRNP70 | c.986_988del p.D329del | In Frame Del (DEL) | VAF 50/147 reads (34%) | called by pindel, varscan2
- SNTB1 | c.731T>C p.I244T | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- SOCS7 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 98/254 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- SRGAP2 | c.2243T>A p.F748Y (on ENST00000624873 / NM_001170637.4; = p.F749Y on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ST6GALNAC4 | c.315G>T p.Q105H | Missense Mutation (SNP) | VAF 106/290 reads (37%) | PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SYN1 | c.1750G>A p.G584R | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBC1D10B | c.1882C>A p.L628M | Missense Mutation (SNP) | VAF 77/235 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TBL3 | c.223A>G p.S75G | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- TBX4 | c.1111_1112del p.P371Sfs*14 | Frame Shift Del (DEL) | VAF 41/122 reads (34%) | called by pindel, varscan2
- TCEA3 | c.495_496insA p.L166Ifs*39 | Frame Shift Ins (INS) | VAF 77/233 reads (33%) | called by mutect2, pindel, varscan2
- TEK | c.565T>C p.Y189H | Missense Mutation (SNP) | VAF 135/409 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- TERB1 | c.365_368del p.S122Ffs*18 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- TIGD2 | c.295G>T p.G99* | Nonsense Mutation (SNP) | VAF 66/181 reads (36%) | called by muse, mutect2, varscan2
- TIMELESS | c.2631G>T p.K877N | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- TLK1 | c.968A>G p.Q323R | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); called by muse, varscan2
- TNFSF12-TNFSF13 | c.43del p.E15Sfs*57 | Frame Shift Del (DEL) | VAF 21/73 reads (29%) | called by mutect2, pindel, varscan2
- TPR | c.2687del p.N896Mfs*9 | Frame Shift Del (DEL) | VAF 44/219 reads (20%) | called by mutect2, pindel, varscan2
- TRAV1-2 | c.298T>G p.S100A | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); called by muse, mutect2
- TRAV3 | c.277T>G p.F93V | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- TRBV23-1 | c.138del p.G47Dfs*19 | Frame Shift Del (DEL) | VAF 31/103 reads (30%) | called by mutect2, pindel, varscan2
- TRPV4 | c.2554del p.R852Afs*35 | Frame Shift Del (DEL) | VAF 33/203 reads (16%) | called by mutect2, pindel, varscan2
- TTC39C | c.422A>T p.Y141F (on ENST00000317571 / NM_001135993.2; = p.Y80F on NM_153211.4) | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0.047); called by muse, varscan2
- TTLL5 | c.1559_1561del p.A520del | In Frame Del (DEL) | VAF 34/84 reads (40%) | called by pindel, varscan2
- TTN | c.78124A>G p.K26042E (on ENST00000591111; = p.K18618E on NM_003319.4) | Missense Mutation (SNP) | VAF 62/161 reads (39%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TUT4 | c.1707G>T p.K569N | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- UNCX | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); called by muse, varscan2
- UQCRC2 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- USH2A | c.7432T>C p.S2478P | Missense Mutation (SNP) | VAF 35/648 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.069); called by muse, mutect2
- USP16 | c.868G>C p.V290L | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- USP35 | c.1502dup p.E502Rfs*103 | Frame Shift Ins (INS) | VAF 48/172 reads (28%) | called by mutect2, pindel, varscan2
- USP39 | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- USP9X | c.7147del p.R2383Efs*6 | Frame Shift Del (DEL) | VAF 44/129 reads (34%) | called by mutect2, pindel, varscan2
- USPL1 | c.2588_2592del p.L863Pfs*14 | Frame Shift Del (DEL) | VAF 36/136 reads (26%) | called by pindel, varscan2
- VASH2 | c.233dup p.E79Rfs*46 (on ENST00000517399 / NM_001301056.2; = p.E79Rfs*54 on NM_024749.5) | Frame Shift Ins (INS) | VAF 52/359 reads (14%) | called by mutect2, pindel, varscan2
- WDR72 | c.278A>G p.N93S | Missense Mutation (SNP) | VAF 101/327 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- WWC3 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 65/145 reads (45%) | called by muse, mutect2, varscan2
- ZBED1 | c.1936T>C p.F646L | Missense Mutation (SNP) | VAF 66/202 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- ZBTB11 | c.2626C>T p.H876Y | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZC2HC1A | c.698A>G p.H233R | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZCCHC3 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- ZNF292 | c.1092T>A p.N364K | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2
- ZNF296 | c.264G>T p.W88C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF469 | c.5619del p.I1874Yfs*24 (on ENST00000437464; = p.I1902Yfs*24 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 171/478 reads (36%) | called by mutect2, pindel, varscan2
- ZNF536 | c.3644C>T p.S1215F | Missense Mutation (SNP) | VAF 64/210 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF672 | c.1301C>T p.T434I | Missense Mutation (SNP) | VAF 61/278 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF792 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNFX1 | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ABCA2 | c.1239T>C p.A413= (on ENST00000614293; = p.A383= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/103 reads (35%) | catalogued as rs890991270; called by muse, mutect2, varscan2
- ADAP1 | c.291G>A p.T97= | Silent (SNP) | VAF 36/103 reads (35%) | catalogued as rs886144845; called by muse, mutect2, varscan2
- ADORA3 | c.528C>T p.Y176= | Silent (SNP) | VAF 77/188 reads (41%) | catalogued as rs754687706; called by muse, mutect2, varscan2
- ADRB1 | c.177G>A p.A59= | Silent (SNP) | VAF 69/201 reads (34%) | catalogued as rs751191292; called by muse, mutect2, varscan2
- AFF4 | c.3379C>T p.L1127= | Silent (SNP) | VAF 64/180 reads (36%) | called by muse, mutect2, varscan2
- AGT | c.1027C>T p.L343= | Silent (SNP) | VAF 132/711 reads (19%) | catalogued as rs1263387254; called by muse, mutect2, varscan2
- AKNA | c.4062C>T p.A1354= | Silent (SNP) | VAF 28/268 reads (10%) | catalogued as rs558717087; called by muse, mutect2, varscan2
- APOA2 | c.177C>T p.A59= | Silent (SNP) | VAF 134/744 reads (18%) | catalogued as rs370208442; called by muse, mutect2, varscan2
- AQP5 | c.291C>T p.G97= | Silent (SNP) | VAF 102/247 reads (41%) | called by muse, mutect2, varscan2
- ARAP3 | c.1668A>G p.V556= | Silent (SNP) | VAF 36/171 reads (21%) | called by muse, mutect2, varscan2
- ARHGEF17 | c.1047G>A p.P349= | Silent (SNP) | VAF 19/170 reads (11%) | called by muse, mutect2, varscan2
- ARHGEF40 | c.2193G>A p.L731= | Silent (SNP) | VAF 6/91 reads (7%) | called by muse, mutect2
- ASB4 | c.814C>T p.L272= | Silent (SNP) | VAF 85/206 reads (41%) | called by muse, mutect2, varscan2
- BAHD1 | c.1560T>C p.H520= | Silent (SNP) | VAF 57/190 reads (30%) | called by muse, mutect2, varscan2
- BMP2K | c.2472T>C p.S824= | Silent (SNP) | VAF 33/97 reads (34%) | called by muse, mutect2, varscan2
- BMP4 | c.855C>A p.T285= | Silent (SNP) | VAF 51/129 reads (40%) | catalogued as rs1319753678; called by muse, mutect2, varscan2
- BRAP | c.186G>A p.Q62= | Silent (SNP) | VAF 49/109 reads (45%) | catalogued as rs1398741063; called by muse, mutect2, varscan2
- C12orf56 | c.1578T>C p.P526= (on ENST00000543942 / NM_001170633.2; = p.P366= on NM_001099676.3) | Silent (SNP) | VAF 40/107 reads (37%) | called by muse, mutect2, varscan2
- C20orf194 | c.3510T>C p.H1170= | Silent (SNP) | VAF 42/121 reads (35%) | called by muse, mutect2, varscan2
- C8B | c.660G>A p.T220= | Silent (SNP) | VAF 153/394 reads (39%) | catalogued as rs370360066; called by muse, mutect2, varscan2
- CAMK2D | c.477C>G p.G159= | Silent (SNP) | VAF 67/199 reads (34%) | called by muse, mutect2, varscan2
- CD9 | c.630C>A p.G210= | Silent (SNP) | VAF 44/125 reads (35%) | called by muse, mutect2, varscan2
- CDCA5 | c.396C>T p.D132= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as rs765815329, COSV51870761; called by muse, mutect2, varscan2
- CDX4 | c.399C>T p.G133= | Silent (SNP) | VAF 73/173 reads (42%) | called by muse, mutect2, varscan2
- CEBPB | c.603G>A p.A201= | Silent (SNP) | VAF 66/157 reads (42%) | catalogued as rs997116351; called by muse, mutect2, varscan2
- CEP126 | c.357G>A p.Q119= | Silent (SNP) | VAF 55/186 reads (30%) | called by muse, mutect2, varscan2
- COL23A1 | c.402C>T p.D134= | Silent (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- COL8A2 | c.1296G>A p.T432= | Silent (SNP) | VAF 92/250 reads (37%) | catalogued as rs762703964; called by muse, mutect2, varscan2
- COL9A2 | c.1350C>T p.P450= | Silent (SNP) | VAF 121/337 reads (36%) | catalogued as COSV65622262; called by muse, mutect2, varscan2
- CSRNP1 | c.1563A>G p.T521= | Silent (SNP) | VAF 59/216 reads (27%) | called by muse, mutect2, varscan2
- CUEDC1 | c.468C>T p.I156= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs111753270; called by muse, mutect2, varscan2
- DLL4 | c.999T>C p.C333= | Silent (SNP) | VAF 68/175 reads (39%) | catalogued as rs773508830; called by muse, mutect2, varscan2
- DMXL2 | c.5664T>C p.T1888= | Silent (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- DMXL2 | c.2418G>A p.L806= | Silent (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2, varscan2
- DNM3 | c.2013C>T p.S671= (on ENST00000355305 / NM_001350206.2; = p.S665= on NM_015569.5) | Silent (SNP) | VAF 50/266 reads (19%) | called by muse, mutect2, varscan2
- E2F8 | c.907T>C p.L303= | Silent (SNP) | VAF 44/109 reads (40%) | called by muse, mutect2, varscan2
- EPS8L3 | c.846A>G p.A282= | Silent (SNP) | VAF 90/296 reads (30%) | called by muse, mutect2, varscan2
- EVX2 | c.1257T>C p.G419= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as rs1197853839; called by mutect2, varscan2
- F11R | c.450G>A p.V150= | Silent (SNP) | VAF 92/540 reads (17%) | called by muse, mutect2, varscan2
- F13A1 | c.2148A>G p.R716= | Silent (SNP) | VAF 150/421 reads (36%) | catalogued as COSV53555828; called by muse, mutect2, varscan2
- FAAP100 | c.2235C>T p.V745= | Silent (SNP) | VAF 70/184 reads (38%) | catalogued as rs768330250; called by muse, mutect2, varscan2
- FAM47A | c.2235C>T p.S745= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as COSV60494333, COSV60495887; called by muse, mutect2, varscan2
- FBN1 | c.4539C>T p.C1513= | Silent (SNP) | VAF 126/382 reads (33%) | catalogued as CM065178; called by muse, mutect2, varscan2
- FBXL3 | c.810T>C p.H270= | Silent (SNP) | VAF 5/105 reads (5%) | called by muse, mutect2
- FIZ1 | c.669C>T p.T223= | Silent (SNP) | VAF 32/102 reads (31%) | catalogued as COSV55608000; called by muse, mutect2, varscan2
- FRMD1 | c.1248C>T p.D416= | Silent (SNP) | VAF 98/267 reads (37%) | catalogued as rs755246476, COSV51959768; called by muse, mutect2, varscan2
- FTMT | c.177C>A p.T59= | Silent (SNP) | VAF 59/138 reads (43%) | called by muse, mutect2, varscan2
- GALNT7 | c.1782A>G p.K594= | Silent (SNP) | VAF 16/174 reads (9%) | called by muse, mutect2
- GPATCH4 | c.714T>C p.A238= | Silent (SNP) | VAF 93/497 reads (19%) | called by muse, mutect2, varscan2
- GPR25 | c.726G>A p.S242= | Silent (SNP) | VAF 81/438 reads (18%) | catalogued as COSV58498341, COSV58499242; called by muse, mutect2, varscan2
- H4C1 | c.96G>A p.K32= | Silent (SNP) | VAF 68/205 reads (33%) | called by muse, mutect2, varscan2
- HCAR1 | c.657C>A p.T219= | Silent (SNP) | VAF 103/258 reads (40%) | catalogued as rs767155988; called by muse, mutect2, varscan2
- HDAC5 | c.2208G>A p.T736= | Silent (SNP) | VAF 45/98 reads (46%) | catalogued as rs372547487, COSV56820860; called by muse, mutect2, varscan2
- HECTD4 | c.10530G>A p.L3510= | Silent (SNP) | VAF 57/137 reads (42%) | catalogued as rs1202396543; called by muse, mutect2, varscan2
- HIRIP3 | c.873C>T p.S291= | Silent (SNP) | VAF 11/124 reads (9%) | catalogued as rs765119373, COSV54231273; called by muse, mutect2
- HMX3 | c.132G>A p.P44= | Silent (SNP) | VAF 28/93 reads (30%) | called by muse, mutect2, varscan2
- HTR1F | c.153C>T p.T51= | Silent (SNP) | VAF 100/311 reads (32%) | catalogued as COSV60390448; called by muse, mutect2, varscan2
- IGF1R | c.2445C>T p.C815= | Silent (SNP) | VAF 85/222 reads (38%) | called by muse, mutect2, varscan2
- IGFBP5 | c.751C>T p.L251= | Silent (SNP) | VAF 70/182 reads (38%) | called by muse, varscan2
- INO80D | c.2325T>G p.L775= | Silent (SNP) | VAF 86/216 reads (40%) | catalogued as rs530833163; called by muse, mutect2, varscan2
- INSYN2B | c.240G>A p.S80= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs1033924671, COSV56991757; called by muse, mutect2, varscan2
- ITGA2 | c.531T>G p.V177= | Silent (SNP) | VAF 110/285 reads (39%) | called by muse, mutect2, varscan2
- KBTBD11 | c.1644G>A p.T548= | Silent (SNP) | VAF 44/119 reads (37%) | called by muse, mutect2, varscan2
- KCND2 | c.114C>A p.T38= | Silent (SNP) | VAF 65/148 reads (44%) | called by muse, mutect2, varscan2
- KIF21B | c.4521C>T p.I1507= (on ENST00000422435 / NM_001252100.2; = p.I1494= on NM_017596.4) | Silent (SNP) | VAF 62/380 reads (16%) | catalogued as rs267598287; called by muse, mutect2, varscan2
- KIF26B | c.2340C>T p.A780= | Silent (SNP) | VAF 64/335 reads (19%) | catalogued as rs532973058, COSV63644934; called by muse, mutect2, varscan2
- KLHL14 | c.1872A>C p.V624= | Silent (SNP) | VAF 51/114 reads (45%) | catalogued as COSV63831821; called by muse, mutect2, varscan2
- KLHL21 | c.1560C>T p.Y520= | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as rs377290952; called by muse, mutect2
- KLHL34 | c.693C>T p.D231= | Silent (SNP) | VAF 78/166 reads (47%) | catalogued as rs981857318, COSV65278721; called by muse, mutect2, varscan2
- LAMC2 | c.508C>A p.R170= | Silent (SNP) | VAF 65/406 reads (16%) | called by muse, mutect2, varscan2
- LRRC17 | c.880C>T p.L294= | Silent (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- MAS1L | c.570T>C p.S190= | Silent (SNP) | VAF 17/133 reads (13%) | catalogued as COSV65808475; called by muse, mutect2, varscan2
- MASTL | c.2397A>G p.E799= (on ENST00000375940 / NM_001372029.1; = p.E798= on NM_032844.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/186 reads (9%) | catalogued as COSV60910449; called by muse, mutect2
- ME1 | c.540C>T p.C180= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as rs754174776, COSV100866438; called by muse, mutect2, varscan2
- MRC1 | c.1908G>A p.P636= | Silent (SNP) | VAF 129/543 reads (24%) | catalogued as rs781948465; called by muse, mutect2, varscan2
- MS4A15 | c.297C>T p.H99= (on ENST00000405633 / NM_001098835.2; = p.H6= on NM_152717.3) | Silent (SNP) | VAF 40/122 reads (33%) | called by muse, mutect2, varscan2
- MTUS1 | c.1671G>A p.P557= | Silent (SNP) | VAF 92/297 reads (31%) | catalogued as rs745717647; called by muse, mutect2, varscan2
- NAIF1 | c.168C>T p.N56= | Silent (SNP) | VAF 30/220 reads (14%) | catalogued as rs1340661373; called by muse, mutect2, varscan2
- NCOR2 | c.4638C>T p.H1546= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs1469646094; called by muse, mutect2, varscan2
- NFAT5 | c.1680T>C p.S560= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as rs1031086836; called by muse, mutect2, varscan2
- NFX1 | c.285G>A p.S95= | Silent (SNP) | VAF 76/235 reads (32%) | catalogued as rs777875408, COSV100582094; called by muse, mutect2, varscan2
- NOTCH3 | c.5451A>C p.S1817= | Silent (SNP) | VAF 113/275 reads (41%) | catalogued as COSV54625230; called by muse, mutect2, varscan2
- NPIPB11 | c.3087T>A p.R1029= | Silent (SNP) | VAF 169/468 reads (36%) | called by muse, mutect2, varscan2
- NR4A2 | c.1119C>T p.V373= | Silent (SNP) | VAF 157/424 reads (37%) | catalogued as COSV59894390; called by muse, mutect2, varscan2
- OXR1 | c.1767T>C p.H589= (on ENST00000442977 / NM_001198532.1; = p.H588= on NM_018002.3) | Silent (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- PCDH17 | c.1518C>T p.T506= | Silent (SNP) | VAF 133/304 reads (44%) | called by muse, mutect2, varscan2
- PCDHA4 | c.1902G>A p.T634= | Silent (SNP) | VAF 218/477 reads (46%) | catalogued as COSV100793181, COSV100793358; called by muse, mutect2, varscan2
- PCK1 | c.846C>T p.A282= | Silent (SNP) | VAF 12/147 reads (8%) | catalogued as rs554852774, COSV60127751; called by muse, mutect2
- PLXNA1 | c.2322C>T p.Y774= | Silent (SNP) | VAF 111/291 reads (38%) | catalogued as rs147176760; called by muse, mutect2, varscan2
- PNPT1 | c.1875C>T p.G625= | Silent (SNP) | VAF 56/172 reads (33%) | called by muse, mutect2, varscan2
- POU4F1 | c.777C>T p.C259= | Silent (SNP) | VAF 106/273 reads (39%) | called by muse, mutect2, varscan2
- PPP1R12B | c.960G>A p.E320= | Silent (SNP) | VAF 25/87 reads (29%) | called by muse, mutect2, varscan2
- PPP1R35 | c.229C>A p.R77= | Silent (SNP) | VAF 37/85 reads (44%) | called by muse, mutect2, varscan2
- RALY | c.468G>A p.R156= (on ENST00000246194 / NM_016732.3; = p.R140= on NM_007367.4) | Silent (SNP) | VAF 74/230 reads (32%) | called by muse, mutect2, varscan2
- RBBP5 | c.132T>C p.N44= | Silent (SNP) | VAF 81/482 reads (17%) | called by muse, mutect2, varscan2
- RELB | c.1587C>T p.P529= | Silent (SNP) | VAF 48/84 reads (57%) | catalogued as rs770384014, COSV55510863; called by muse, mutect2, varscan2
- REV3L | c.6048C>T p.Y2016= | Silent (SNP) | VAF 74/187 reads (40%) | catalogued as rs753982547, COSV62617280; called by muse, mutect2, varscan2
- RYBP | c.603C>T p.S201= | Silent (SNP) | VAF 124/301 reads (41%) | called by muse, mutect2, varscan2
- SERTAD2 | c.333G>A p.A111= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs779794166, COSV100512224; called by muse, mutect2, varscan2
- SETBP1 | c.1431A>G p.S477= | Silent (SNP) | VAF 206/548 reads (38%) | called by muse, varscan2
- SHF | c.1050T>C p.S350= | Silent (SNP) | VAF 100/229 reads (44%) | catalogued as rs1474701053; called by muse, mutect2, varscan2
- SKIDA1 | c.2298T>C p.P766= | Silent (SNP) | VAF 13/270 reads (5%) | called by muse, mutect2
- SLC12A1 | c.897T>C p.N299= | Silent (SNP) | VAF 65/155 reads (42%) | called by muse, mutect2, varscan2
- SLC4A7 | c.3234G>A p.P1078= | Silent (SNP) | VAF 70/187 reads (37%) | catalogued as rs747613260, COSV55403551; called by muse, mutect2, varscan2
- SLC5A9 | c.651G>A p.T217= | Silent (SNP) | VAF 51/187 reads (27%) | catalogued as rs61730938, COSV52581784, COSV99361310; called by muse, mutect2, varscan2
- SMARCC2 | c.1155T>C p.D385= | Silent (SNP) | VAF 67/184 reads (36%) | called by muse, mutect2, varscan2
- SMOC2 | c.399C>T p.C133= | Silent (SNP) | VAF 18/342 reads (5%) | catalogued as rs1181873339, COSV100635660, COSV99080536; called by muse, mutect2
- SNAP91 | c.1830T>G p.T610= | Silent (SNP) | VAF 55/171 reads (32%) | called by muse, mutect2, varscan2
- SOGA1 | c.4887G>A p.S1629= | Silent (SNP) | VAF 23/176 reads (13%) | catalogued as rs1181936454; called by muse, mutect2, varscan2
- SORBS1 | c.1173A>T p.S391= (on ENST00000361941 / NM_001034954.2; = p.S227= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 55/109 reads (50%) | called by muse, mutect2, varscan2
- SORL1 | c.2940G>A p.Q980= | Silent (SNP) | VAF 61/152 reads (40%) | called by muse, mutect2, varscan2
- SSTR4 | c.378C>T p.D126= | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as rs770914493, COSV54796826; called by muse, mutect2, varscan2
- TAPBPL | c.685C>T p.L229= | Silent (SNP) | VAF 116/334 reads (35%) | catalogued as rs1161833645; called by muse, mutect2, varscan2
- TARS2 | c.231C>T p.N77= | Silent (SNP) | VAF 36/173 reads (21%) | called by muse, mutect2, varscan2
- TAS2R3 | c.384G>A p.R128= | Silent (SNP) | VAF 51/123 reads (41%) | called by muse, mutect2, varscan2
- TBL1X | c.540C>T p.A180= | Silent (SNP) | VAF 60/170 reads (35%) | catalogued as rs767736403; called by muse, varscan2
- TFCP2L1 | c.972G>A p.S324= | Silent (SNP) | VAF 58/187 reads (31%) | catalogued as rs772260501, COSV55292569; called by muse, mutect2, varscan2
- TINAGL1 | c.297T>C p.F99= | Silent (SNP) | VAF 17/122 reads (14%) | called by muse, mutect2
- TMEM132C | c.1287C>T p.G429= | Silent (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- TMEM169 | c.387G>A p.L129= | Silent (SNP) | VAF 102/288 reads (35%) | catalogued as rs367789628; called by muse, mutect2, varscan2
- TMEM266 | c.792G>A p.A264= | Silent (SNP) | VAF 56/179 reads (31%) | catalogued as rs1325330594, COSV66381073; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3678C>T p.D1226= | Silent (SNP) | VAF 26/220 reads (12%) | called by muse, mutect2, varscan2
- TNN | c.2721G>A p.P907= | Silent (SNP) | VAF 117/511 reads (23%) | catalogued as rs141014433; called by muse, mutect2, varscan2
- TRAPPC12 | c.762C>T p.P254= | Silent (SNP) | VAF 71/151 reads (47%) | catalogued as rs774631193; called by muse, mutect2, varscan2
- TRIM9 | c.258C>T p.S86= | Silent (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- TWSG1 | c.141G>A p.R47= | Silent (SNP) | VAF 60/155 reads (39%) | called by muse, mutect2, varscan2
- USH2A | c.8826C>T p.D2942= | Silent (SNP) | VAF 57/277 reads (21%) | catalogued as rs775823422; called by muse, mutect2, varscan2
- WFS1 | c.1728C>T p.G576= | Silent (SNP) | VAF 109/283 reads (39%) | called by muse, mutect2, varscan2
- ZNF251 | c.180G>A p.K60= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as rs766617370; called by muse, mutect2, varscan2
- ZNF257 | c.1212A>G p.E404= | Silent (SNP) | VAF 74/156 reads (47%) | catalogued as rs775808287; called by muse, mutect2, varscan2
- ZNF544 | c.1680C>T p.N560= | Silent (SNP) | VAF 42/107 reads (39%) | called by muse, mutect2, varscan2
- ZNF546 | c.2148T>C p.T716= | Silent (SNP) | VAF 12/99 reads (12%) | called by muse, mutect2, varscan2
- ZNF556 | c.1092A>G p.Q364= | Silent (SNP) | VAF 72/182 reads (40%) | catalogued as rs1266486918; called by muse, mutect2, varscan2
- ZNF644 | c.1824G>A p.L608= | Silent (SNP) | VAF 63/160 reads (39%) | called by muse, mutect2, varscan2
- ZXDB | c.1122C>T p.P374= | Silent (SNP) | VAF 99/334 reads (30%) | called by muse, mutect2, varscan2
- AC093155.3 | c.767-1049C>T | Intron (SNP) | VAF 74/195 reads (38%) | catalogued as rs961641651; called by muse, mutect2, varscan2
- AC107023.1 | chr12:40444462 G>A | 5'Flank (SNP) | VAF 37/126 reads (29%) | called by muse, mutect2, varscan2
- ACADVL | c.1182+72del | Intron (DEL) | VAF 26/103 reads (25%) | called by mutect2, pindel, varscan2
- ACP4 | chr19:50798250 G>A | 3'Flank (SNP) | VAF 45/109 reads (41%) | catalogued as rs1021594886; called by muse, mutect2, varscan2
- ADAM22 | c.992+35del | Intron (DEL) | VAF 10/42 reads (24%) | catalogued as rs1345745155; called by mutect2, pindel, varscan2
- AF186192.2 | chr8:144698889 del G | 5'Flank (DEL) | VAF 37/113 reads (33%) | catalogued as rs939045252; called by mutect2, pindel, varscan2
- AFDN | chr6:167976177 ins G | 3'Flank (INS) | VAF 22/95 reads (23%) | catalogued as rs1219378445; called by mutect2, pindel
- AGAP1 | c.163+29686del | Intron (DEL) | VAF 6/11 reads (55%) | called by mutect2, varscan2
- ALG6 | c.82+30del | Intron (DEL) | VAF 23/80 reads (29%) | catalogued as rs559834759, COSV54763801; called by mutect2, varscan2
- ANXA8 | c.*181C>T | 3'UTR (SNP) | VAF 145/808 reads (18%) | called by muse, mutect2, varscan2
- ARL13B | c.130+613del | Intron (DEL) | VAF 23/72 reads (32%) | called by mutect2, pindel, varscan2
- ARPP21 | c.898-10del | Intron (DEL) | VAF 30/88 reads (34%) | catalogued as rs751740483; called by mutect2, varscan2
- BCS1L | c.321-47C>T | Intron (SNP) | VAF 14/436 reads (3%) | called by muse, mutect2
- CCDC50 | c.-48G>A | 5'UTR (SNP) | VAF 71/204 reads (35%) | called by muse, mutect2, varscan2
- CDC14B | c.160+668C>T | Intron (SNP) | VAF 85/267 reads (32%) | called by muse, mutect2, varscan2
- CDCA7 | c.*25T>C | 3'UTR (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2
- CDK5RAP3 | chr17:47971080 C>A | 5'Flank (SNP) | VAF 42/122 reads (34%) | called by muse, mutect2, varscan2
- COX17 | c.107+347G>A | Intron (SNP) | VAF 35/136 reads (26%) | catalogued as rs1225020051; called by muse, mutect2, varscan2
- DDX11 | c.638+900G>A | Intron (SNP) | VAF 118/379 reads (31%) | catalogued as rs1215835829; called by muse, mutect2, varscan2
- DHRS9 | c.1del | 5'UTR (DEL) | VAF 20/57 reads (35%) | called by mutect2, pindel, varscan2
- DMXL2 | c.7923+24A>G | Intron (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- DOK6 | c.-36C>T | 5'UTR (SNP) | VAF 93/220 reads (42%) | catalogued as rs1218006178, COSV101235037; called by muse, mutect2, varscan2
- EXOC6 | c.458+16del | Intron (DEL) | VAF 28/128 reads (22%) | catalogued as rs758347935; called by mutect2, pindel, varscan2
- FAM181A | c.100-576C>T | Intron (SNP) | VAF 32/111 reads (29%) | called by muse, mutect2, varscan2
- FAM205BP | n.1977G>A | RNA (SNP) | VAF 102/393 reads (26%) | called by mutect2, varscan2
- FAM230J | n.730G>T | RNA (SNP) | VAF 43/207 reads (21%) | called by muse, mutect2, varscan2
- FANCC | c.996+1559dup | Intron (INS) | VAF 85/248 reads (34%) | called by mutect2, varscan2
- FBXO24 | c.39+75T>A | Intron (SNP) | VAF 134/329 reads (41%) | catalogued as rs767611802; called by muse, mutect2, varscan2
- FXR1 | c.51+2875del | Intron (DEL) | VAF 43/144 reads (30%) | catalogued as rs756396894; called by mutect2, varscan2
- GHRHR | c.974+50del | Intron (DEL) | VAF 47/166 reads (28%) | called by mutect2, pindel, varscan2
- GNAS | c.2068+240C>T | Intron (SNP) | VAF 73/203 reads (36%) | catalogued as rs967732544; called by muse, mutect2, varscan2
- GOLGA4 | c.-67G>A | 5'UTR (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- GPM6B | c.-11dup | 5'UTR (INS) | VAF 16/66 reads (24%) | called by mutect2, pindel, varscan2
- HAND2 | c.555+16C>T | Intron (SNP) | VAF 99/259 reads (38%) | catalogued as rs779116452, COSV64019028, COSV64019408; called by muse, mutect2, varscan2
- HMGA1 | c.*321del | 3'UTR (DEL) | VAF 57/164 reads (35%) | called by mutect2, pindel, varscan2
- IKBKB | c.*9del | 3'UTR (DEL) | VAF 69/189 reads (37%) | called by mutect2, varscan2
- JAKMIP2 | c.2413-2775T>C | Intron (SNP) | VAF 61/143 reads (43%) | called by muse, mutect2, varscan2
- KCNC3 | c.*1385C>T | 3'UTR (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- LARS2 | c.*865G>A | 3'UTR (SNP) | VAF 66/204 reads (32%) | catalogued as COSV99648458; called by muse, mutect2, varscan2
- LINC00269 | n.431C>T | RNA (SNP) | VAF 102/235 reads (43%) | catalogued as rs1309911114; called by muse, mutect2, varscan2
- LIPT2 | chr11:74497761 C>A | 5'Flank (SNP) | VAF 56/125 reads (45%) | called by muse, mutect2, varscan2
- LITAF | c.*816del | 3'UTR (DEL) | VAF 39/90 reads (43%) | catalogued as rs758850868; ClinVar: uncertain significance; called by mutect2, varscan2
- LRATD1 | c.*704del | 3'UTR (DEL) | VAF 83/301 reads (28%) | called by mutect2, pindel, varscan2
- LRRC8D | c.-141C>T | 5'UTR (SNP) | VAF 54/154 reads (35%) | called by muse, mutect2, varscan2
- MIRLET7BHG | n.170G>A | RNA (SNP) | VAF 74/200 reads (37%) | catalogued as rs149867851; called by muse, mutect2
- MUC19 | chr12:40421242 del A | 3'Flank (DEL) | VAF 6/23 reads (26%) | catalogued as rs746639059; called by mutect2, pindel, varscan2
- MUCL3 | c.946+868A>G | Intron (SNP) | VAF 61/301 reads (20%) | catalogued as rs1305952989, COSV58516256; called by muse, mutect2, varscan2
- NAV2 | c.268-54564G>T | Intron (SNP) | VAF 85/209 reads (41%) | catalogued as COSV62328604; called by muse, mutect2, varscan2
- NDRG1 | c.-18-521G>A | Intron (SNP) | VAF 37/107 reads (35%) | catalogued as rs1260862917; called by muse, mutect2, varscan2
- NEDD4L | c.2548-12T>A | Intron (SNP) | VAF 19/136 reads (14%) | called by muse, mutect2, varscan2
- NPHP4 | c.2611+609A>T | Intron (SNP) | VAF 9/93 reads (10%) | called by muse, mutect2
- NPM2 | c.-33-18C>T | Intron (SNP) | VAF 55/129 reads (43%) | catalogued as rs367880291; called by muse, mutect2, varscan2
- NRIP3 | c.*612G>A | 3'UTR (SNP) | VAF 34/91 reads (37%) | catalogued as rs1339089593, COSV100487129; called by muse, mutect2, varscan2
- PADI1 | c.*96dup | 3'UTR (INS) | VAF 165/533 reads (31%) | called by mutect2, pindel, varscan2
- PARGP1 | n.1410G>A | RNA (SNP) | VAF 39/192 reads (20%) | called by muse, mutect2, varscan2
- PCSK6 | c.2699+61G>A | Intron (SNP) | VAF 53/157 reads (34%) | called by muse, mutect2, varscan2
- PLEKHD1 | c.243+99C>T | Intron (SNP) | VAF 15/32 reads (47%) | called by mutect2, varscan2
- PLSCR3 | c.286+9_286+11del | Intron (DEL) | VAF 113/359 reads (31%) | catalogued as rs1291758147; called by mutect2, pindel, varscan2
- PNPLA6 | c.-21C>A | 5'UTR (SNP) | VAF 46/165 reads (28%) | called by muse, mutect2, varscan2
- PRKCB | c.-5G>A | 5'UTR (SNP) | VAF 122/255 reads (48%) | called by muse, mutect2, varscan2
- RAB18 | c.*3191C>T | 3'UTR (SNP) | VAF 26/358 reads (7%) | called by muse, mutect2
- RNF125 | c.319-36del | Intron (DEL) | VAF 45/137 reads (33%) | called by mutect2, pindel, varscan2
- RP1 | c.*41dup | 3'UTR (INS) | VAF 32/111 reads (29%) | catalogued as rs774193905; called by mutect2, pindel, varscan2
- RPL3 | c.366-170C>T | Intron (SNP) | VAF 20/62 reads (32%) | catalogued as rs1330518912; called by muse, mutect2
- SH3PXD2B | c.*4526C>T | 3'UTR (SNP) | VAF 59/127 reads (46%) | called by muse, mutect2, varscan2
- SNAP47 | c.1249-4721G>A | Intron (SNP) | VAF 47/240 reads (20%) | catalogued as rs566590122; called by muse, mutect2, varscan2
- SNORD115-23 | n.10A>G | RNA (SNP) | VAF 78/206 reads (38%) | called by muse, mutect2, varscan2
- SRD5A3 | c.-33dup | 5'UTR (INS) | VAF 36/129 reads (28%) | called by mutect2, pindel
- SSPOP | n.4489T>C | RNA (SNP) | VAF 73/197 reads (37%) | catalogued as rs1244283974; called by muse, mutect2, varscan2
- STAB1 | c.4364-40del | Intron (DEL) | VAF 31/93 reads (33%) | called by mutect2, pindel, varscan2
- TAFA5 | c.-21del | 5'UTR (DEL) | VAF 54/182 reads (30%) | catalogued as COSV100387150; called by pindel, varscan2
- TGFBR3 | c.*1838del | 3'UTR (DEL) | VAF 21/46 reads (46%) | catalogued as rs201044103; called by mutect2, varscan2
- TMIE | c.-47C>T | 5'UTR (SNP) | VAF 16/139 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.-63G>A | 5'UTR (SNP) | VAF 29/107 reads (27%) | catalogued as rs1434970080; called by muse, mutect2, varscan2
- UBE3A | c.*31del | 3'UTR (DEL) | VAF 18/48 reads (38%) | catalogued as rs750480224; called by mutect2, varscan2
- UBR2 | c.1281+157G>A | Intron (SNP) | VAF 35/119 reads (29%) | catalogued as rs978399522; called by muse, mutect2, varscan2
- UQCRB | c.*2040_*2041del | 3'UTR (DEL) | VAF 62/216 reads (29%) | called by pindel, varscan2
- XAF1 | c.850-16del | Intron (DEL) | VAF 9/90 reads (10%) | catalogued as rs1391680282; called by mutect2, pindel, varscan2
- XIAP | c.*5630C>T | 3'UTR (SNP) | VAF 36/103 reads (35%) | called by muse, varscan2
- ZFYVE21 | c.190-177T>C | Intron (SNP) | VAF 38/300 reads (13%) | called by muse, mutect2, varscan2
